Somatic mutation profile of tumor specimen TCGA-J4-A67T-01A (aliquot TCGA-J4-A67T-01A-11D-A30X-08) from TCGA case TCGA-J4-A67T, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.5 years (23,211 days).
Specimen TCGA-J4-A67T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66c15bea-1107-43cf-a79e-dcf0e21a4f3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67T-10A (Blood Derived Normal), aliquot TCGA-J4-A67T-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98743333-f77c-400f-8d24-41929336bc7a

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 5, Silent 5, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as COSV67129951; called by muse, mutect2, varscan2
- F5 | c.2985G>T p.Q995H | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV63125689; called by muse, mutect2, varscan2
- KPRP | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); catalogued as rs1403896561, COSV64221515; called by muse, mutect2
- LTBP2 | c.2462G>A p.G821E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs776897363, COSV56210378, COSV56215048; called by muse, mutect2, varscan2
- PPRC1 | c.3893A>G p.Y1298C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53386719; called by muse, mutect2, varscan2
- ZFR | c.1468A>T p.T490S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV54055073; called by muse, mutect2, varscan2
- ROBO1 | c.4204del p.D1402Tfs*15 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- ZC3H13 | c.2988del p.G997Dfs*40 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel, varscan2
- COL25A1 | c.1467C>T p.D489= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs1218096575, COSV67652866, COSV67656141; called by muse, mutect2, varscan2
- DPPA4 | c.231G>A p.K77= | Silent (SNP) | VAF 8/164 reads (5%) | catalogued as rs1409766135, COSV59511441; called by muse, mutect2
- LCT | c.4761C>T p.R1587= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs573401319, COSV51545280, COSV51552658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS2 | c.744C>T p.T248= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs376465256; called by muse, mutect2, varscan2
- PTH2R | c.429C>T p.R143= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as rs760355827, COSV55917534; called by muse, mutect2, varscan2
